Gene-level copy-number profile of tumor specimen MP2PRT-PAPDIV-TMP1-A from MP2PRT case MP2PRT-PAPDIV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (779 days).
Specimen MP2PRT-PAPDIV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0195fb0a-bd48-4b9d-8daa-fad771a7963a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPDIV-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/d51d5ed0-4211-4f3a-a2a7-e473a40aba9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 570; copy number 2: 31,471; copy number 3: 18,636; copy number 4: 2,238; copy number 5: 5,937.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,275,787, 45 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–5): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,937 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,550,284–42,657,105, 569 genes, copy number 5 (broad region; genes not listed).
- chr4:49,203,171–49,489,554, 8 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3.
- chr4:82,128,535–89,841,978, 137 genes, copy number 5 (broad region; genes not listed).
- chr4:97,120,701–104,494,901, 98 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:107,590,276–118,460,301, 151 genes, copy number 5 (broad region; genes not listed).
- chr4:138,664,725–170,142,532, 450 genes, copy number 5 (broad region; genes not listed).
- chr4:182,881,777–190,092,279, 159 genes, copy number 5 (broad region; genes not listed).
- chr14:18,555,677–19,714,332, 65 genes, copy number 5 (broad region; genes not listed).
- chr14:20,684,177–22,418,657, 128 genes, copy number 5 (broad region; genes not listed).
- chr14:22,455,249–105,845,678, 1,804 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr14:106,276,548–106,879,812, 99 genes, copy number 5 (broad region; genes not listed).
- chr17:19,061,912–21,419,870, 137 genes, copy number 5 (broad region; genes not listed).
- chr17:21,442,805–21,451,525, 2 genes, copy number 5: AC068418.3, PDLIM1P2.
- chr17:22,090,743–46,555,650, 991 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:46,537,534–46,537,814, 1 gene, copy number 5 (within-gene range 2–5): RN7SL199P.
- chr17:46,590,669–83,240,804, 1,138 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
